CCDI case PBBVHA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/a1c607d8-d994-4744-8bbd-db8f52a3a9dd

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of head, face, and neck; Age at diagnosis: 0.8 years (304 days).

Biospecimens (3 samples)
- Sample 0DL8PX: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DL8Q4: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DL8QL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
